Somatic mutation profile of tumor specimen MP2PRT-PAVHMR-TMP1-A (aliquot MP2PRT-PAVHMR-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVHMR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.9 years (3,244 days).
Specimen MP2PRT-PAVHMR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54271ca4-08a6-4840-9ced-80d0ea84ca71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHMR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHMR-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6c46887-9939-411d-8026-879723c85888

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT4 | c.10570C>T p.R3524W | Missense Mutation (SNP) | VAF 72/429 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs145569482; called by muse, mutect2, varscan2
- HLA-B | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 136/292 reads (47%) | catalogued as rs151341185, CM1412118; called by muse, varscan2
- WIZ | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1398904784; called by muse, mutect2
- C10orf90 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 14/526 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); called by muse, mutect2
- FNBP1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 15/410 reads (4%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.947); called by muse, mutect2
- HLA-B | c.891dup p.W298Mfs*36 | Frame Shift Ins (INS) | VAF 19/234 reads (8%) | called by mutect2, pindel
- SLC6A14 | c.1781A>C p.Q594P | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2
- TLE2 | c.1760G>A p.G587D | Missense Mutation (SNP) | VAF 13/357 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
